Somatic mutation profile of tumor specimen TCGA-BR-8360-01A (aliquot TCGA-BR-8360-01A-11D-2340-08) from TCGA case TCGA-BR-8360, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 66.8 years (24,394 days).
Specimen TCGA-BR-8360-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f10d4569-505a-4e02-9237-66eff4ff0aad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8360-10A (Blood Derived Normal), aliquot TCGA-BR-8360-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/938540d7-6af7-42e9-811b-713a216f81af

The open-access MAF lists 1,047 somatic variants for this specimen: 778 protein-altering or splice-affecting, 243 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 522, Silent 243, Frame Shift Del 167, Frame Shift Ins 37, Nonsense Mutation 23, Splice Site 13, In Frame Del 13, RNA 9, Intron 8, 3'UTR 5, Splice Region 2, 5'Flank 2.

Variants (750 of 1,047; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs759055242, COSV53146939; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.2588dup p.N863Kfs*18 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | catalogued as rs80359335; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 57/216 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 37/122 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC18A2 | c.711del p.F238Sfs*48 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs762879329, COSV53693545; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCA13 | c.11783A>G p.D3928G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV71284860; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCC9 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53966281, COSV53988533; called by muse, mutect2, varscan2
- ABCF1 | c.856G>A p.V286M (on ENST00000326195 / NM_001025091.2; = p.V248M on NM_001090.3) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as rs1422039008, COSV58230545; called by muse, mutect2, varscan2
- ABCF1 | c.1183C>T p.R395W (on ENST00000326195 / NM_001025091.2; = p.R357W on NM_001090.3) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs989406749, COSV58229226; called by muse, mutect2, varscan2
- ABHD16A | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758057318, COSV65451449; called by muse, mutect2, varscan2
- ABR | c.1528G>A p.V510I (on ENST00000302538 / NM_021962.5; = p.V473I on NM_001092.5) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as rs1435336473, COSV52141668; called by muse, mutect2, varscan2
- AC007040.2 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55539609; called by muse, mutect2, varscan2
- AC008676.3 | c.635del p.G212Vfs*24 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as rs748255153; called by mutect2, pindel, varscan2
- AC092143.1 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs886042295, COSV59247953; called by muse, mutect2, varscan2
- ACAD10 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs932721321, COSV58155123; called by muse, mutect2, varscan2
- ACRBP | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs114920773; called by muse, mutect2, varscan2
- ACSS1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs775016558, COSV60222349; called by muse, mutect2
- ACTR1A | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64024370; called by muse, mutect2, varscan2
- ADAMTS14 | c.2624G>T p.R875L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV64607129; called by muse, mutect2, varscan2
- ADAMTS2 | c.2348C>A p.A783D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV52396924; called by muse, mutect2, varscan2
- ADAMTS5 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53186217; called by muse, mutect2, varscan2
- ADAMTS7 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1283878925, COSV66307663; called by muse, mutect2, varscan2
- ADCY2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57904248; called by muse, mutect2, varscan2
- ADCY8 | c.2555G>T p.R852L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53931384, COSV53931398; called by muse, mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADGRB2 | c.4601G>T p.S1534I (on ENST00000373658 / NM_001364857.2; = p.S1533I on NM_001294335.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV99925925; called by muse, mutect2
- ADGRB3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs754848273, COSV65395147, COSV65421513; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- ADRA1D | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV65242200; called by muse, mutect2, varscan2
- ADRA2A | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54527914; called by muse, mutect2, varscan2
- AFDN | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs1475005866, COSV60058961; called by muse, mutect2, varscan2
- AGO1 | c.49dup p.L17Pfs*28 | Frame Shift Ins (INS) | VAF 22/73 reads (30%) | catalogued as rs752471592; called by mutect2, varscan2
- AIRE | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs768840365, COSV52393715; called by muse, mutect2, varscan2
- AKR1B10 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV62056791; called by muse, mutect2, varscan2
- ALDH1L1 | c.1746G>A p.W582* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV56420061; called by muse, mutect2, varscan2
- ALDH5A1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62374663; called by muse, mutect2, varscan2
- ALKBH1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs950826692, COSV53661628; called by muse, mutect2, varscan2
- ALPL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs138690664, CM980079; called by muse, mutect2, varscan2
- ALS2 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM125682, COSV51893701; called by muse, mutect2, varscan2
- AMER3 | c.585del p.R196Gfs*70 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as COSV58470642; called by mutect2, pindel, varscan2
- ANK1 | c.4789G>T p.G1597C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV55898036; called by muse, mutect2, varscan2
- ANKLE2 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61712050; called by muse, mutect2, varscan2
- ANO7 | c.413G>T p.R138M (on ENST00000274979; = p.R83M on NM_001001666.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV51480306; called by muse, mutect2, varscan2
- AOX1 | c.1046T>A p.I349N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65984570; called by muse, mutect2, varscan2
- APMAP | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs201595930, COSV54177352; called by muse, mutect2, varscan2
- ARAP1 | c.3142C>T p.R1048C (on ENST00000393609 / NM_001040118.2; = p.R803C on NM_015242.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.189); catalogued as rs753832901, COSV61995684; called by muse, mutect2, varscan2
- ARF1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV55256221; called by muse, mutect2, varscan2
- ARFGEF2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.274); catalogued as COSV64213761; called by muse, mutect2, varscan2
- ARHGAP10 | c.312+2T>C p.X104_splice | Splice Site (SNP) | VAF 42/63 reads (67%) | catalogued as COSV60608017; called by muse, mutect2, varscan2
- ARHGEF16 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs1048897523, COSV65683453; called by muse, mutect2, varscan2
- ASB10 | c.1301G>A p.R434H (on ENST00000420175 / NM_001142459.2; = p.R419H on NM_080871.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758074125, COSV52001248; called by muse, mutect2, varscan2
- ASCC2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1450458158, COSV57077035; called by muse, mutect2, varscan2
- ASPM | c.8271A>T p.K2757N | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.173); catalogued as COSV54140282; called by muse, mutect2, varscan2
- ASTE1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs753155621, COSV53910840; called by muse, mutect2, varscan2
- ASTN1 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56088815; called by muse, mutect2, varscan2
- ATAD2 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 33/156 reads (21%) | catalogued as COSV54887670; called by muse, mutect2, varscan2
- ATP1A4 | c.60A>T p.R20S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV63628880; called by muse, mutect2
- ATP6V1C2 | c.964-2A>T p.X322_splice (on ENST00000272238 / NM_001039362.2; = p.X276_splice on NM_144583.4) | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99694528; called by muse, mutect2
- ATP9A | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs138665384, COSV58772875; called by muse, mutect2, varscan2
- AXL | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs776776986, COSV56569765; called by muse, varscan2
- B3GALT4 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs149120716; called by muse, mutect2, varscan2
- BCAM | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs144233028, COSV54305476; called by muse, varscan2
- BCAS2 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65767930; called by muse, mutect2, varscan2
- BCL11B | c.1735G>A p.A579T (on ENST00000357195 / NM_001282237.2; = p.A508T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as rs1274911424, COSV61735499, COSV61740298; called by muse, mutect2, varscan2
- BCO2 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs766237700, COSV63065230; called by muse, mutect2, varscan2
- BMP4 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768059149, COSV55417442; called by muse, mutect2, varscan2
- BNC2 | c.2489C>A p.P830Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV66158799; called by muse, mutect2
- BPI | c.494G>A p.S165N (on ENST00000262865; = p.S161N on NM_001725.3) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53408928; called by muse, mutect2, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs777474487; called by mutect2, varscan2
- BRCA1 | c.1829G>T p.R610M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV58801654; called by muse, mutect2, varscan2
- BRINP1 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56315155; called by muse, mutect2, varscan2
- BRINP3 | c.614T>G p.I205R | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66543436; called by muse, mutect2, varscan2
- BUB1B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs587778144, COSV55010377; ClinVar: not provided; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CACNA1G | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61741420; called by muse, mutect2, varscan2
- CADM3 | c.532C>T p.R178C (on ENST00000368125 / NM_001127173.3; = p.R212C on NM_021189.5) | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV63684367, COSV63687799; called by muse, mutect2, varscan2
- CALHM2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778156770, COSV53295670; called by muse, mutect2, varscan2
- CAMTA1 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs149702154, COSV57898613; called by muse, mutect2, varscan2
- CASP5 | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52832407; called by muse, mutect2, varscan2
- CASQ1 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63624631; called by muse, mutect2, varscan2
- CCDC150 | c.175del p.R59Efs*10 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs34248242; called by mutect2, pindel, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC172 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.04); catalogued as COSV60940776; called by muse, varscan2
- CCR3 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62466370; called by muse, mutect2, varscan2
- CCSER2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV56513605; called by muse, mutect2, varscan2
- CD93 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755090767, COSV55669328; called by muse, mutect2, varscan2
- CDC42EP2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs139397769, COSV54204114; called by muse, mutect2, varscan2
- CDH10 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52582083; called by muse, mutect2, varscan2
- CDH3 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374738611; called by muse, mutect2, varscan2
- CDH8 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as rs756389319, COSV54852308; called by muse, mutect2, varscan2
- CDKN2D | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs765322862, COSV57266076; called by muse, mutect2, varscan2
- CELSR3 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756196478, COSV50879887; called by muse, mutect2, varscan2
- CEND1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.158); catalogued as COSV57195296; called by muse, mutect2, varscan2
- CENPB | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60150490; called by muse, mutect2
- CEP192 | c.3059_3061dup p.Q1020dup | In Frame Ins (INS) | VAF 41/167 reads (25%) | catalogued as rs1234476784; called by mutect2, varscan2
- CEP290 | c.7341del p.K2447Nfs*10 | Frame Shift Del (DEL) | VAF 36/141 reads (26%) | catalogued as rs281865189; ClinVar: not provided; called by mutect2, pindel
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 36/165 reads (22%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP95 | c.2094A>C p.E698D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV73609698; called by muse, mutect2, varscan2
- CEP97 | c.100T>C p.C34R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1466233308, COSV59124917; called by muse, mutect2, varscan2
- CHD4 | c.5162G>T p.R1721L (on ENST00000357008 / NM_001363606.2; = p.R1732L on NM_001273.5) | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58910378; called by muse, mutect2, varscan2
- CHD4 | c.4177C>T p.R1393C (on ENST00000357008 / NM_001363606.2; = p.R1406C on NM_001273.5) | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58904895, COSV58912315; called by muse, mutect2, varscan2
- CHRD | c.1321-2A>G p.X441_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV52613208; called by muse, mutect2, varscan2
- CHST10 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 96/313 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs148953500; called by muse, mutect2, varscan2
- CHST13 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV60043421; called by muse, mutect2, varscan2
- CHST15 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as rs1165652161, COSV60566298; called by muse, mutect2, varscan2
- CHST8 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); catalogued as rs916046058, COSV52856983; called by muse, mutect2, varscan2
- CLCNKA | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58894397; called by muse, mutect2, varscan2
- CMTM7 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs1416635465, COSV58549814, COSV58552353; called by muse, mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 41/216 reads (19%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- COP1 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1222131072, COSV58178065; called by muse, mutect2, varscan2
- CORO1A | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1206523159, COSV54632310; called by muse, mutect2, varscan2
- COTL1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs374406128, COSV52289786, COSV52291304; called by muse, mutect2, varscan2
- CPAMD8 | c.3499G>A p.A1167T (on ENST00000651564; = p.A1120T on NM_015692.5) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs372897642; called by muse, mutect2, varscan2
- CRYBA2 | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55387511; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | catalogued as rs762650691; called by mutect2, varscan2
- CTSG | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV53537118; called by muse, mutect2, varscan2
- CUEDC1 | c.1034+1G>A p.X345_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as rs777359766, COSV64227397; called by muse, mutect2, varscan2
- CWF19L1 | c.1262C>A p.P421H | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62499667, COSV62499889; called by muse, mutect2, varscan2
- CXXC1 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV53274379, COSV53277253; called by muse, mutect2, varscan2
- CYP11B2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV59998216; called by muse, mutect2, varscan2
- CYP26A1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56419057; called by muse, mutect2, varscan2
- CYP2A6 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56534568; called by muse, mutect2, varscan2
- CYP4F22 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs369811543; called by muse, mutect2, varscan2
- CYTH2 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57310981; called by muse, mutect2, varscan2
- CYTH4 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs371162850; called by muse, mutect2, varscan2
- DAAM2 | c.3193C>T p.R1065W (on ENST00000274867 / NM_001201427.2; = p.R1064W on NM_015345.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs775538347, COSV51347996; called by muse, mutect2, varscan2
- DAB2IP | c.688_690del p.K230del (on ENST00000408936; = p.K202del on NM_032552.3) | In Frame Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1028731832; called by pindel, varscan2
- DCAF13 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52574931; called by muse, mutect2, varscan2
- DENND2B | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV58208311; called by muse, mutect2, varscan2
- DEUP1 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV53217461; called by muse, mutect2
- DHCR24 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.613); catalogued as rs150166147; called by muse, mutect2, varscan2
- DHX58 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV52428609; called by muse, mutect2, varscan2
- DHX9 | c.1796A>G p.D599G | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs757918330, COSV62359232; called by muse, mutect2, varscan2
- DIDO1 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56613654; called by muse, mutect2, varscan2
- DIPK1B | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs371582245; called by muse, mutect2, varscan2
- DKK4 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766494052, COSV55184343; called by muse, mutect2, varscan2
- DNAH2 | c.2135T>A p.L712H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66728424; called by muse, mutect2, varscan2
- DNAH5 | c.8837G>A p.R2946H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs140975593; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAI3 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54006796; called by muse, mutect2, varscan2
- DNAJB13 | c.475dup p.I159Nfs*2 | Frame Shift Ins (INS) | VAF 16/57 reads (28%) | catalogued as rs754363435; called by mutect2, varscan2
- DNHD1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV54444265; called by muse, mutect2, varscan2
- DNMBP | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs374602494, COSV100143949; called by muse, mutect2
- DOK3 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57254636; called by muse, mutect2, varscan2
- DSCAM | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs977050001, COSV68025859; called by muse, mutect2, varscan2
- DST | c.17861G>A p.R5954H (on ENST00000361203 / NM_001374722.1; = p.R3651H on NM_015548.5) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs1433627829, COSV55044741; called by muse, mutect2, varscan2
- DTNB | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs368115598, COSV56485731; called by muse, mutect2, varscan2
- DUSP5 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.117); catalogued as COSV63647682; called by muse, varscan2
- DYDC2 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV55473765; called by muse, mutect2, varscan2
- DYSF | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778316824, CM1410224, COSV50290549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3214G>A p.A1072T | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34660230, COSV50638265; called by muse, mutect2, varscan2
- E4F1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770063253, COSV57041638; called by muse, mutect2, varscan2
- EHBP1L1 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs1342033770, COSV58575446; called by muse, mutect2, varscan2
- EIF2AK3 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1434600602, COSV57550056, COSV57552838; called by muse, mutect2, varscan2
- EIF3A | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64963045; called by muse, varscan2
- ELAC2 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs147779718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELF4 | c.1388T>C p.F463S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV57455566; called by muse, mutect2, varscan2
- ELFN2 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1287690574, COSV68743856; called by muse, mutect2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | catalogued as COSV53155402; called by mutect2, pindel, varscan2
- ENOSF1 | c.979A>T p.T327S (on ENST00000340116 / NM_001354066.2; = p.T279S on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV51896151; called by muse, mutect2, varscan2
- EPHA7 | c.2555G>A p.G852D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.41); PolyPhen probably damaging (1); catalogued as rs1287261842, COSV65181008, COSV65193252; called by muse, mutect2, varscan2
- EPHX1 | c.1041-1G>A p.X347_splice | Splice Site (SNP) | VAF 23/86 reads (27%) | catalogued as COSV55304500; called by muse, mutect2, varscan2
- ETV1 | c.913A>C p.T305P | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54152669; called by muse, mutect2, varscan2
- EZR | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61456540; called by muse, mutect2, varscan2
- F2RL2 | c.988T>A p.Y330N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs969191202, COSV56971589, COSV56972269; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM124B | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs377743341; called by muse, mutect2, varscan2
- FAM13B | c.2010del p.K670Nfs*15 | Frame Shift Del (DEL) | VAF 46/159 reads (29%) | catalogued as COSV50367448; called by mutect2, pindel, varscan2
- FAM155A | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV65590759; called by muse, varscan2
- FAM167A | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746960113, COSV52668053; called by muse, mutect2, varscan2
- FAT2 | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs773412435, COSV55819166; called by muse, mutect2, varscan2
- FBXL18 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs376064015, COSV66668335; called by muse, mutect2, varscan2
- FBXO41 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs865871335, COSV54590221; called by muse, mutect2, varscan2
- FCGBP | c.9484C>T p.P3162S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as rs545740519; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel
- FCN2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs371833675, COSV52479340; called by muse, mutect2, varscan2
- FDXR | c.1312T>C p.Y438H (on ENST00000293195 / NM_024417.5; = p.Y444H on NM_004110.6) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV53118600; called by muse, mutect2, varscan2
- FGD3 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61600332; called by muse, mutect2, varscan2
- FGFR3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as rs779284979, COSV53395349; called by muse, mutect2, varscan2
- FHL3 | c.21_22del p.A8Kfs*25 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs746025611; called by pindel, varscan2
- FHOD3 | c.4103G>A p.R1368H (on ENST00000359247 / NM_001281739.3; = p.R1385H on NM_025135.5) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs781253442, COSV57173649; called by muse, mutect2, varscan2
- FILIP1L | c.839G>T p.R280I (on ENST00000354552 / NM_182909.3; = p.R40I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV58777217; called by muse, mutect2, varscan2
- FLG | c.10484C>T p.S3495L | Missense Mutation (SNP) | VAF 87/504 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64251222; called by muse, mutect2, varscan2
- FLG | c.6776G>A p.R2259Q | Missense Mutation (SNP) | VAF 88/495 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs542918091, COSV64246345; called by muse, mutect2, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs755445139; called by mutect2, varscan2
- FNDC1 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as COSV51949088; called by muse, mutect2
- FOXD4L1 | c.327del p.Y110Tfs*52 | Frame Shift Del (DEL) | VAF 30/214 reads (14%) | catalogued as rs1398223087; called by pindel, varscan2
- FOXL1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV57215428; called by muse, mutect2, varscan2
- FOXN3 | c.1261C>T p.R421C (on ENST00000261302; = p.R399C on NM_005197.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); catalogued as COSV54318140; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FUT6 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs375534466; called by mutect2, varscan2
- FZD3 | c.888dup p.T297Yfs*25 | Frame Shift Ins (INS) | VAF 24/110 reads (22%) | catalogued as rs765036679; called by mutect2, varscan2
- G6PD | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63704884; called by muse, mutect2, varscan2
- GAK | c.2974G>A p.V992I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs772475111, COSV100033315, COSV58510687; called by muse, mutect2, varscan2
- GAL3ST1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58893808; called by muse, mutect2, varscan2
- GDF3 | c.591T>A p.N197K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100325395, COSV61714001; called by muse, mutect2, varscan2
- GDPGP1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762850072, COSV61576322; called by muse, mutect2, varscan2
- GGT7 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309939860, COSV60543123; called by muse, mutect2, varscan2
- GLCCI1 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56205828; called by muse, mutect2, varscan2
- GMPPB | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV57537452; called by muse, mutect2, varscan2
- GMPS | c.1082_1084del p.E361del | In Frame Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs1339366430; called by pindel, varscan2
- GOLGA2 | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70168970; called by muse, mutect2, varscan2
- GP5 | c.113del p.G38Afs*9 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs750629635; called by mutect2, varscan2
- GPHN | c.1354C>T p.R452W (on ENST00000315266 / NM_001377519.1; = p.R485W on NM_020806.5) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59495321; called by muse, mutect2, varscan2
- GPR45 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs903481209, COSV51525098; called by muse, mutect2, varscan2
- GPRASP1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs780359209, COSV64356619; called by muse, mutect2, varscan2
- GRIN3A | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs145862529, COSV62455621; called by muse, mutect2
- GRIN3A | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62459181; called by muse, mutect2, varscan2
- GRIP1 | c.1785A>C p.K595N (on ENST00000359742 / NM_001379345.1; = p.K543N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs1565721288, COSV54045859; called by muse, mutect2, varscan2
- GRK2 | c.1354T>C p.F452L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57952161; called by muse, mutect2, varscan2
- GRK4 | c.650del p.K217Sfs*7 (on ENST00000398052 / NM_182982.3; = p.K185Sfs*7 on NM_005307.3) | Frame Shift Del (DEL) | VAF 40/187 reads (21%) | catalogued as rs1335893291; called by mutect2, pindel, varscan2
- GRM6 | c.1894T>G p.F632V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51450595; called by muse, mutect2, varscan2
- GTPBP10 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV55989219; called by muse, mutect2, varscan2
- GTPBP2 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200065, COSV61077515; called by muse, varscan2
- GTPBP6 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as rs1194368062, COSV100397687; called by muse, mutect2, varscan2
- HAO2 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV58039500, COSV58042598; called by muse, mutect2, varscan2
- HECTD4 | c.7538A>G p.Y2513C | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66400964; called by muse, mutect2, varscan2
- HLA-F | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs955096239, COSV52577606; called by muse, mutect2, varscan2
- HMBOX1 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.066); catalogued as COSV55072693; called by muse, mutect2, varscan2
- HOGA1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs779027672, COSV56730779; called by muse, mutect2, varscan2
- HOXA9 | c.660A>T p.E220D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58656833; called by muse, mutect2, varscan2
- HOXB1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV53318915; called by muse, mutect2, varscan2
- HOXB13 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51705162; called by muse, mutect2, varscan2
- HRH2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51573110; called by muse, mutect2, varscan2
- HSPA6 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1305401466, COSV59063059; called by muse, mutect2, varscan2
- HTR1E | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV59511622; called by muse, mutect2, varscan2
- HTR1E | c.801del p.F268Sfs*5 | Frame Shift Del (DEL) | VAF 64/227 reads (28%) | catalogued as rs753568078, COSV59508996, COSV59509296; called by mutect2, varscan2
- HTR7 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53293871; called by muse, mutect2, varscan2
- HUNK | c.1487-1G>A p.X496_splice | Splice Site (SNP) | VAF 23/94 reads (24%) | catalogued as rs1253358322, COSV54235304; called by muse, mutect2, varscan2
- IARS2 | c.2113G>T p.V705F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.733); catalogued as COSV56958743; called by muse, mutect2, varscan2
- IBTK | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376082045; called by muse, mutect2, varscan2
- IFT172 | c.2137G>A p.G713S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99562070; called by muse, mutect2
- IGFL4 | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV66619100; called by muse, mutect2, varscan2
- IGSF8 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.858); catalogued as rs767148569, COSV58759373; called by muse, mutect2, varscan2
- IL2RA | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56922330; called by muse, mutect2, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | catalogued as rs745545309; called by mutect2, varscan2
- ILKAP | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467065123, COSV54518277, COSV54520596; called by muse, varscan2
- INSIG2 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55524034; called by muse, mutect2, varscan2
- INSRR | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1039215180, COSV63875729; called by muse, mutect2, varscan2
- INTS11 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV60090642; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 55/259 reads (21%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- INTU | c.2527C>T p.R843C | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778337257, COSV58869392; called by muse, mutect2, varscan2
- IPO11 | c.716del p.L239Yfs*8 | Frame Shift Del (DEL) | VAF 27/101 reads (27%) | catalogued as COSV100321224; called by mutect2, pindel, varscan2
- ITGAD | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as COSV66760670; called by muse, mutect2
- ITGAE | c.1801del p.L601Wfs*82 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs867709180; called by mutect2, pindel, varscan2
- ITPR3 | c.5492C>T p.A1831V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs776342387, COSV65415552; called by muse, mutect2, varscan2
- ITPRID1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750560323, COSV60072418; called by muse, mutect2, varscan2
- IWS1 | c.1745del p.K582Sfs*4 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs1558747232; called by mutect2, pindel, varscan2
- IZUMO1 | c.419-1G>T p.X140_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99710643; called by muse, mutect2, varscan2
- JAKMIP1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV51547166; called by muse, mutect2, varscan2
- JCAD | c.3929G>A p.R1310H | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs1434802738, COSV64762034; called by muse, mutect2, varscan2
- KALRN | c.5015C>T p.T1672M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375684753; called by muse, mutect2, varscan2
- KBTBD3 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.714); catalogued as rs1212274447, COSV73241658; called by muse, mutect2, varscan2
- KCMF1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs746409862, COSV69055002; called by muse, mutect2, varscan2
- KCNA1 | c.1225T>A p.S409T | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as COSV66838943; called by muse, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNIP1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61081139; called by muse, mutect2, varscan2
- KDR | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs375909858; called by muse, mutect2, varscan2
- KIAA0513 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs755537260, COSV50742168; called by muse, mutect2, varscan2
- KIAA0895L | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as rs750697342, COSV51784129; called by muse, mutect2, varscan2
- KIF1A | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV57503798; called by muse, mutect2, varscan2
- KIF26B | c.3199del p.R1067Gfs*65 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as COSV63639593; called by mutect2, pindel
- KIF27 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1292479233, COSV99926846; called by muse, mutect2, varscan2
- KIFC1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.247); catalogued as rs773177817, COSV65737969; called by muse, mutect2, varscan2
- KLHDC4 | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54511754; called by muse, mutect2, varscan2
- KLHL18 | c.980G>T p.S327I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51748968; called by muse, mutect2, varscan2
- KLHL18 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51748975; called by muse, mutect2, varscan2
- KLHL24 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54425809; called by muse, mutect2, varscan2
- KLK2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs868181466, COSV57570096; called by muse, mutect2, varscan2
- KLK7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58345341; called by muse, mutect2, varscan2
- KNDC1 | c.3595C>T p.R1199C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs772078496, COSV58847548; called by muse, mutect2, varscan2
- KRT33A | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs750904301, COSV50365705; called by muse, mutect2, varscan2
- KRT33B | c.1159A>C p.T387P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52442768; called by muse, mutect2, varscan2
- KRTAP11-1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV60095599; called by muse, mutect2, varscan2
- L3MBTL1 | c.1300G>T p.G434C (on ENST00000418998 / NM_001377303.1; = p.G344C on NM_015478.7) | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64229814; called by muse, mutect2, varscan2
- LAMB2 | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs775598935, COSV59735723; called by muse, mutect2, varscan2
- LAMC1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51185675; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs746633076; called by mutect2, varscan2
- LDHD | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs761717844, COSV55581880, COSV55582218; called by muse, mutect2, varscan2
- LDLRAD1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64956420; called by muse, mutect2, varscan2
- LEMD1 | c.110del p.K37Sfs*2 | Frame Shift Del (DEL) | VAF 58/160 reads (36%) | catalogued as rs774476336, COSV65671631; called by mutect2, pindel, varscan2
- LMNTD1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV51451334; called by muse, mutect2, varscan2
- LMX1A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs778377042, COSV54218498, COSV54225933; called by muse, mutect2, varscan2
- LPIN1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56771834; called by muse, mutect2, varscan2
- LRFN3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV55819292; called by muse, mutect2, varscan2
- LRIG3 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57870910; called by muse, mutect2, varscan2
- LRP1 | c.4166C>A p.P1389Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54528517; called by muse, mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 25/87 reads (29%) | catalogued as rs139915490; called by mutect2, varscan2
- LRP12 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.069); catalogued as COSV52635424; called by muse, mutect2, varscan2
- LRP1B | c.4723T>A p.F1575I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1461861485, COSV67281513; called by muse, mutect2, varscan2
- LRP2 | c.8387G>A p.R2796H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.607); catalogued as rs552943504, COSV55550196; called by muse, mutect2, varscan2
- LRRC17 | c.581G>C p.S194T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV50868734; called by muse, mutect2, varscan2
- LRRC25 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53251831; called by muse, mutect2, varscan2
- LRRTM3 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as COSV63672772; called by muse, mutect2, varscan2
- LSR | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV61556029; called by muse, mutect2, varscan2
- LY6E | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52870683; called by muse, mutect2, varscan2
- LZTS3 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs545635836, COSV61277391; called by mutect2, varscan2
- MAG | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62702708; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAGEL2 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as rs781530773, COSV58569523; called by muse, mutect2, varscan2
- MAMSTR | c.485dup p.H163Tfs*9 (on ENST00000318083 / NM_001130915.2; = p.H60Tfs*9 on NM_182574.2) | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | catalogued as rs752869239; called by mutect2, varscan2
- MANBA | c.2611G>A p.A871T (on ENST00000642252; = p.A825T on NM_005908.4) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs182869272, COSV56963400, COSV56971258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP1B | c.6806C>A p.A2269E | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV57107490; called by muse, mutect2, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as COSV67608111; called by mutect2, pindel, varscan2
- MAP3K14 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs558318157, COSV60925299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARCHF11 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs537978378, COSV60135731; called by muse, mutect2, varscan2
- MATN2 | c.404T>G p.M135R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54720733; called by muse, mutect2
- MBD5 | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV68699185; called by muse, mutect2, varscan2
- MCF2L | c.2390C>T p.A797V (on ENST00000375608; = p.A765V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56182601; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED20 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV54826700; called by muse, mutect2, varscan2
- MED25 | c.1859G>A p.G620D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV57207828; called by muse, mutect2, varscan2
- MED30 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764507160, COSV52067752; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs745891632; called by mutect2, varscan2
- MESP2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs781296717; called by muse, mutect2
- METTL1 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55745905; called by muse, mutect2, varscan2
- METTL17 | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1566434700, COSV53871300; called by muse, mutect2, varscan2
- MEX3A | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs760022238, COSV68479352; called by muse, mutect2
- MFHAS1 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52287485; called by muse, mutect2, varscan2
- MGA | c.4544G>T p.G1515V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV54964497; called by muse, mutect2, varscan2
- MICAL2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56327391; called by muse, mutect2, varscan2
- MICAL3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV52906532; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MICU2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138030448; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIGA2 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.114); catalogued as rs576542776, COSV52978703; called by muse, mutect2, varscan2
- MMP11 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747596627, COSV53157726; called by muse, mutect2, varscan2
- MMP9 | c.823+1G>A p.X275_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV63434574; called by muse, mutect2, varscan2
- MNDA | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs776081749, COSV63741202, COSV63741216; called by muse, varscan2
- MPRIP | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1367276093, COSV57930681; called by muse, mutect2
- MROH1 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1410401494; called by mutect2, varscan2
- MRPS25 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53742530; called by muse, mutect2, varscan2
- MSANTD4 | c.561del p.F187Lfs*19 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | catalogued as rs1475601536; called by mutect2, pindel
- MTBP | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1380791075, COSV100011922, COSV59966971; called by muse, mutect2, varscan2
- MTERF1 | c.1046C>A p.P349H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61098440; called by muse, mutect2, varscan2
- MTUS2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs377003171, COSV54994077; called by muse, mutect2, varscan2
- MUC16 | c.8284A>C p.S2762R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.148); catalogued as COSV67450803, COSV67499420; called by muse, mutect2, varscan2
- MUC3A | c.8737T>C p.S2913P | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1249526987; called by muse, mutect2, varscan2
- MYH13 | c.3392C>T p.T1131M | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs749855584, COSV52845336; called by muse, mutect2, varscan2
- MYO1F | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754452234, COSV57791886; called by muse, mutect2, varscan2
- MYO9A | c.6200G>A p.R2067H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as rs747452822, COSV61847926; called by muse, mutect2, varscan2
- MYOF | c.6065G>A p.R2022H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs754851421, COSV63711614; called by muse, mutect2, varscan2
- NAA30 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs756820517, COSV53649922; called by muse, mutect2, varscan2
- NAV2 | c.5152G>A p.A1718T (on ENST00000396087 / NM_001244963.2; = p.A1662T on NM_145117.5) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60666308; called by muse, mutect2, varscan2
- NBAS | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs557345395, COSV55712787; called by muse, varscan2
- NCAM1 | c.1685C>A p.A562D (on ENST00000316851 / NM_181351.5; = p.A552D on NM_000615.7) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100377290; called by muse, mutect2, varscan2
- NCAM1 | c.1825C>T p.Q609* (on ENST00000316851 / NM_181351.5; = p.Q599* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV57514833; called by muse, mutect2
- NCAN | c.2102C>G p.P701R | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV53057295, COSV53060362; called by muse, mutect2, varscan2
- NDUFB11 | c.386G>A p.R129Q (on ENST00000377811 / NM_001135998.3; = p.R139Q on NM_019056.6) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52101897; called by muse, mutect2, varscan2
- NEB | c.19603C>T p.R6535W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561904743, COSV51437348, COSV51465619; ClinVar: uncertain significance; called by muse, mutect2
- NECAB3 | c.913G>A p.A305T (on ENST00000246190 / NM_031232.4; = p.A271T on NM_031231.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.326); catalogued as COSV55778953; called by muse, mutect2, varscan2
- NEK10 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV55366401; called by muse, mutect2, varscan2
- NEK10 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as rs1408535070, COSV58290290; called by muse, mutect2, varscan2
- NEU2 | c.1044del p.L349Cfs*21 | Frame Shift Del (DEL) | VAF 55/222 reads (25%) | catalogued as COSV52091819; called by mutect2, pindel, varscan2
- NKAIN2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV63691532; called by muse, varscan2
- NKAPL | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59199582; called by muse, mutect2, varscan2
- NLGN2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.208); catalogued as COSV57212512; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRP11 | c.1551G>T p.M517I | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1167152514, COSV64088715; called by muse, mutect2, varscan2
- NLRP6 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56462387; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1402340327; called by mutect2, pindel
- NOMO3 | c.1945T>C p.Y649H | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99530758; called by muse, mutect2, varscan2
- NOP58 | c.46-1G>T p.X16_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99970510; called by muse, mutect2, varscan2
- NPAS2 | c.1916C>A p.A639D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.157); catalogued as COSV59563036; called by muse, mutect2, varscan2
- NPLOC4 | c.1302C>G p.N434K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58620357, COSV58621202; called by muse, mutect2, varscan2
- NTN1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); catalogued as rs766128293, COSV51489749; called by muse, mutect2, varscan2
- NTNG1 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.508); catalogued as rs200163382, COSV53991496; called by muse, mutect2, varscan2
- NUP133 | c.1585T>C p.Y529H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54575851; called by muse, mutect2, varscan2
- OCA2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1280092718, COSV62349722; called by muse, mutect2, varscan2
- OLFML3 | c.72C>G p.H24Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57437279; called by muse, mutect2, varscan2
- OPHN1 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1265135988, COSV62781341; called by muse, mutect2, varscan2
- OR13C5 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs372097050; called by muse, mutect2, varscan2
- OR2AT4 | c.598del p.Q200Rfs*37 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs999134663; called by mutect2, pindel, varscan2
- OR2C3 | c.458del p.G153Vfs*2 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs745467477, COSV63574549; called by mutect2, pindel, varscan2
- OR2H2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs771721699, COSV100589643, COSV63542650; called by muse, mutect2, varscan2
- OR4C13 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.208); catalogued as COSV73648920, COSV73648972; called by muse, mutect2, varscan2
- OR52N2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs745461368, COSV57678087; called by muse, mutect2
- OR5AP2 | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV57259283; called by muse, mutect2, varscan2
- OR5P3 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs777463642, COSV60430146; called by muse, mutect2, varscan2
- OR6F1 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV57469721; called by muse, mutect2, varscan2
- OR7G2 | c.583A>C p.I195L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV59689254; called by muse, mutect2, varscan2
- ORC3 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV57644117; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTOF | c.2805G>T p.E935D (on ENST00000272371 / NM_194248.3; = p.E188D on NM_004802.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.675); catalogued as rs1262428439, COSV55522816; called by muse, mutect2, varscan2
- P2RX3 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54445171; called by muse, mutect2, varscan2
- PACSIN3 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs199999369; called by muse, mutect2
- PADI3 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64935558; called by muse, mutect2, varscan2
- PARD3B | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV62533526; called by muse, mutect2, varscan2
- PARD3B | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756215435, COSV62533536; called by muse, mutect2, varscan2
- PCDH7 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62341536; called by muse, mutect2, varscan2
- PCDHA4 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs376395074, COSV63543797; called by muse, mutect2, varscan2
- PCDHGA4 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54048533; called by muse, mutect2, varscan2
- PCF11 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV53529547, COSV53530301; called by muse, mutect2, varscan2
- PDCD11 | c.4421G>A p.R1474Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs761369588, COSV63933580; called by muse, mutect2, varscan2
- PDE3A | c.1232A>T p.E411V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62984158; called by muse, mutect2, varscan2
- PDE4DIP | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs782773952, COSV57694344; called by muse, mutect2, varscan2
- PDGFD | c.640del p.I214Lfs*68 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1333395128; called by mutect2, pindel, varscan2
- PDLIM5 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs757010684, COSV58753517; called by muse, mutect2, varscan2
- PDS5B | c.3592del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs755801132, COSV59734300; called by mutect2, pindel, varscan2
- PDZD2 | c.5810T>C p.V1937A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56875198; called by muse, mutect2, varscan2
- PDZRN3 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs780712940, COSV55217542; called by muse, mutect2, varscan2
- PELI2 | c.593del p.G198Afs*73 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | catalogued as COSV50713636; called by mutect2, pindel, varscan2
- PHF20L1 | c.1602dup p.V535Sfs*13 | Frame Shift Ins (INS) | VAF 25/110 reads (23%) | catalogued as rs1335277934; called by mutect2, varscan2
- PIK3R2 | c.902-2A>G p.X301_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV55850656; called by muse, mutect2, varscan2
- PKN3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753836061, COSV52576239; called by muse, mutect2, varscan2
- PLAGL1 | c.35C>T p.T12M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs1008581224, COSV61334002; called by muse, mutect2, varscan2
- PLCB1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.408); catalogued as COSV62042026, COSV62048712; called by muse, mutect2, varscan2
- PLD5 | c.325C>T p.R109* (on ENST00000442594; = p.R47* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/174 reads (32%) | catalogued as rs771334123, COSV59140511; called by muse, mutect2
- PLEC | c.7619C>T p.A2540V (on ENST00000322810 / NM_201380.4; = p.A2430V on NM_000445.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.05); catalogued as COSV59703379; called by muse, mutect2, varscan2
- PLEKHH1 | c.3999dup p.T1334Hfs*56 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | catalogued as rs761759640; called by mutect2, varscan2
- PLEKHH3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs766227688, COSV53188506; called by muse, mutect2, varscan2
- PLXNA2 | c.3967C>T p.R1323* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs758315833, COSV65438782; called by muse, mutect2, varscan2
- PLXNA4 | c.3583T>A p.S1195T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58164620; called by muse, mutect2, varscan2
- PML | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV51455243; called by muse, mutect2, varscan2
- PNPLA2 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100352008; called by muse, mutect2, varscan2
- POLL | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54577987; called by muse, mutect2, varscan2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 33/120 reads (28%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPM1D | c.1522A>G p.M508V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59958380; called by muse, mutect2, varscan2
- PPP1CC | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV58585399; called by muse, mutect2, varscan2
- PPP3CB | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.753); catalogued as rs749229440, COSV61151584; called by muse, mutect2, varscan2
- PRAMEF14 | c.1368del p.C457Afs*39 | Frame Shift Del (DEL) | VAF 31/114 reads (27%) | catalogued as rs1553186813; called by mutect2, varscan2
- PRB2 | c.248del p.P83Hfs*348 | Frame Shift Del (DEL) | VAF 50/252 reads (20%) | catalogued as rs1296212213, COSV66983609; called by mutect2, varscan2
- PRDM16 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs374937969; called by muse, mutect2, varscan2
- PRDM4 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747069656, COSV57305387; called by muse, varscan2
- PRDM4 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198002284, COSV57307943; called by muse, mutect2, varscan2
- PREB | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53208476; called by muse, mutect2, varscan2
- PRH1 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV101457489; called by muse, mutect2, varscan2
- PRKAR1A | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV62235533; called by muse, mutect2, varscan2
- PRMT5 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV53548665; called by muse, mutect2, varscan2
- PRPF8 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59268505; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRC2A | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs142106114, COSV65689317; called by muse, mutect2, varscan2
- PRRC2A | c.4277G>C p.G1426A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV65685770, COSV65689325; called by muse, mutect2, varscan2
- PRRG3 | c.494dup p.R166Qfs*14 | Frame Shift Ins (INS) | VAF 12/22 reads (55%) | catalogued as rs748526759; called by mutect2, varscan2
- PRRT1 | c.485del p.G162Afs*3 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs1334302334; called by mutect2, pindel, varscan2
- PRSS54 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54691566; called by muse, mutect2, varscan2
- PRUNE2 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65048986; called by muse, mutect2, varscan2
- PRUNE2 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65029919; called by muse, mutect2, varscan2
- PSG11 | c.845C>A p.S282* | Nonsense Mutation (SNP) | VAF 70/251 reads (28%) | catalogued as COSV60458232, COSV60458395; called by muse, mutect2
- PSMA8 | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57605597; called by muse, mutect2, varscan2
- PTCH1 | c.4153C>T p.P1385S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV59497035; called by muse, mutect2, varscan2
- PTER | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as rs370033967; called by muse, mutect2, varscan2
- PTPMT1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768172963, COSV58597994; called by muse, mutect2, varscan2
- PTPRA | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377260441, COSV99399611; called by muse, mutect2, varscan2
- PTPRB | c.4457A>T p.K1486I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54255912; called by muse, mutect2, varscan2
- PTPRC | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553243145, COSV61421433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRG | c.1979G>T p.R660M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV55665419; called by muse, mutect2, varscan2
- PTPRR | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs536591294, COSV51727886; called by muse, mutect2, varscan2
- PXDN | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53247643; called by muse, mutect2, varscan2
- PXDNL | c.4016G>C p.R1339T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs193274927, COSV62499109; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as COSV100234622; called by mutect2, varscan2
- RAB3B | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318221564, COSV65435252; called by muse, mutect2, varscan2
- RAB3GAP1 | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV51489802; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3571T>C p.F1191L | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV62787698; called by muse, mutect2, varscan2
- RABGAP1 | c.2128T>C p.Y710H | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV65381187; called by muse, mutect2, varscan2
- RACK1 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV59322783; called by muse, mutect2, varscan2
- RALGAPA2 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.922); catalogued as rs1482910750, COSV52513360; called by muse, mutect2, varscan2
- RAPGEF1 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV64702731; called by mutect2, varscan2
- RAX | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs776685888, COSV56875535; called by muse, mutect2, varscan2
- RBBP6 | c.3770G>A p.G1257E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV60508998; called by muse, mutect2, varscan2
- RBBP8NL | c.922del p.L308Wfs*15 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs1193757889, COSV53348140; called by mutect2, varscan2
- RGL2 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV69916641; called by muse, varscan2
- RGS1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV100817595, COSV66506739; called by muse, mutect2, varscan2
- RICTOR | c.2261T>C p.L754S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57131948; called by muse, mutect2, varscan2
- RIMS2 | c.3652C>T p.R1218* | Nonsense Mutation (SNP) | VAF 36/162 reads (22%) | catalogued as rs761733020, COSV51730065; called by muse, mutect2, varscan2
- RLN1 | c.479del p.K160Rfs*14 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | catalogued as rs758351039; called by mutect2, pindel, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF10 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 63/197 reads (32%) | catalogued as rs774506367, COSV58048663; called by muse, mutect2, varscan2
- RNF123 | c.2284G>A p.V762I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs1340084259, COSV59693146; called by muse, mutect2
- RNF19A | c.2131C>A p.P711T | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV61993663, COSV61995182; called by muse, mutect2, varscan2
- RNF213 | c.7168G>A p.D2390N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200989987, COSV60410562; called by muse, mutect2, varscan2
- RNF31 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs762748637, COSV53760686, COSV53761575; called by muse, mutect2, varscan2
- ROBO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs754092395, COSV71394997, COSV71396072; called by muse, mutect2, varscan2
- ROPN1B | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs759847011, COSV52543465; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA4 | c.788del p.P263Lfs*112 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as COSV99589846; called by mutect2, varscan2
- RRP8 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1292545865, COSV54450923; called by muse, mutect2, varscan2
- RSPRY1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs1361586314, COSV68028847; called by muse, mutect2, varscan2
- RTL9 | c.1310T>C p.M437T | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV71826558; called by muse, mutect2, varscan2
- RTN2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1176639498, COSV55595122; called by muse, mutect2
- RTTN | c.5402T>G p.L1801R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55353560; called by muse, mutect2, varscan2
- RWDD2B | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs146828876; called by muse, mutect2, varscan2
- RYR2 | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs727504850, COSV100769137, COSV63685455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAFB | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52653755; called by muse, mutect2, varscan2
- SALL1 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746135021, COSV51755278; called by muse, mutect2, varscan2
- SALL3 | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73306690; called by muse, mutect2, varscan2
- SALL3 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV73306692; called by muse, mutect2, varscan2
- SARS1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as rs762645332, COSV52321095; called by muse, mutect2, varscan2
- SATB2 | c.1879G>T p.G627W | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53493675; called by muse, mutect2, varscan2
- SCN9A | c.5656C>T p.R1886W (on ENST00000303354; = p.R1875W on NM_002977.3) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs560168893, COSV57599473; called by muse, mutect2, varscan2
- SEC16A | c.1689del p.F563Lfs*9 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV99255876; called by mutect2, pindel, varscan2
- SECISBP2 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV60530423; called by muse, mutect2, varscan2
- SEMA5B | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52109917; called by muse, mutect2, varscan2
- SEMA6A | c.2637del p.V881Ffs*20 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | catalogued as rs749631581, COSV56712590; called by mutect2, pindel, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINI1 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV55515566; called by muse, varscan2
- SERTAD2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as rs776716971, COSV57640369, COSV57641366; called by muse, varscan2
- SETBP1 | c.3355G>T p.G1119* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV56339022; called by muse, mutect2, varscan2
- SETD1A | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs778079685, COSV52693307; called by muse, mutect2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs759211171; called by mutect2, varscan2
- SFMBT2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV100739324, COSV62814517; called by muse, mutect2, varscan2
- SGPL1 | c.1561G>T p.G521* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | catalogued as COSV64592714; called by muse, mutect2, varscan2
- SH2B3 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57987078; called by muse, mutect2, varscan2
- SHC3 | c.1305G>T p.W435C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV104424920, COSV65441133; called by muse, mutect2, varscan2
- SHOX | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119853, COSV100478895; called by muse, mutect2
- SHPRH | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs763270749, COSV51619076; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs774210627; called by mutect2, pindel, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIM1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs41285857, COSV53489607; called by muse, mutect2, varscan2
- SLAMF7 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as COSV63563614, COSV63564245; called by muse, mutect2, varscan2
- SLC12A4 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57936515; called by muse, mutect2, varscan2
- SLC12A7 | c.1967+2T>C p.X656_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV53763404; called by muse, mutect2, varscan2
- SLC16A10 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64355973; called by muse, mutect2, varscan2
- SLC18A3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60334665; called by muse, mutect2, varscan2
- SLC22A12 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.387); catalogued as rs772733867, COSV60574404; called by muse, mutect2, varscan2
- SLC22A2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs767569658, COSV65268346; called by muse, mutect2, varscan2
- SLC23A1 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100136400; called by muse, mutect2, varscan2
- SLC26A5 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV59706746; called by muse, mutect2, varscan2
- SLC26A8 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs939875741, COSV62885093; called by muse, mutect2, varscan2
- SLC2A6 | c.755A>C p.Q252P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as COSV52469424, COSV52472038; called by muse, mutect2, varscan2
- SLC30A3 | c.1159dup p.Q387Pfs*27 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs747206800; called by mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SLC35G5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs370522572; called by muse, mutect2, varscan2
- SLC5A3 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62974141; called by muse, mutect2, varscan2
- SLC5A6 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60161683; called by muse, mutect2, varscan2
- SLC7A3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs374563735, COSV53226623; called by muse, mutect2, varscan2
- SLC9C1 | c.29dup p.S11Qfs*3 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs749004401; called by mutect2, varscan2
- SLCO1B1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57018373, COSV99918159; called by muse, mutect2, varscan2
- SLITRK5 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1302557415, COSV61526998; called by muse, mutect2, varscan2
- SMARCAL1 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61924193; called by muse, mutect2, varscan2
- SMG8 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs765179613, COSV56283532; called by muse, mutect2, varscan2
- SMTNL2 | c.1315C>T p.R439C (on ENST00000389313 / NM_001114974.2; = p.R295C on NM_198501.3) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1420600438, COSV58808513, COSV58809336; called by muse, varscan2
- SNAPC4 | c.3652C>G p.P1218A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs749148967, COSV100047009; called by muse, mutect2, varscan2
- SNRPD3 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53184302; called by muse, mutect2, varscan2
- SNX32 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs772344561, COSV57449506; called by muse, mutect2, varscan2
- SORL1 | c.1459C>A p.L487I | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV52763883; called by muse, mutect2, varscan2
- SPEG | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs200618676, COSV56681127; called by muse, mutect2, varscan2
- SPIDR | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs782521786, COSV52376476; called by muse, mutect2, varscan2
- SPRED1 | c.797T>C p.M266T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV54439524; called by muse, mutect2, varscan2
- SPSB1 | c.696C>T p.P232= | Splice Region (SNP) | VAF 47/141 reads (33%) | catalogued as rs149018843; called by muse, mutect2, varscan2
- SPTBN5 | c.4151C>A p.P1384H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.412); catalogued as COSV58018832, COSV58029062; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs1470980144, COSV72486131; called by mutect2, pindel, varscan2
- SRPK2 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61965039; called by muse, mutect2, varscan2
- SRSF4 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs769961673, COSV65695895; called by muse, mutect2, varscan2
- SSTR4 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.074); catalogued as COSV54797339, COSV54800598; called by muse, mutect2, varscan2
- SSUH2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.669); catalogued as rs769878746, COSV58033389; called by muse, mutect2, varscan2
- STAB2 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV66348316; called by muse, mutect2, varscan2
- STAG2 | c.1757C>G p.T586S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV54374520; called by muse, mutect2, varscan2
- STC2 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV54182097; called by muse, mutect2, varscan2
- STEAP3 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755328857, COSV61531364; called by muse, mutect2, varscan2
- STEAP4 | c.580del p.L194Cfs*27 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs1305743392; called by mutect2, pindel, varscan2
- STON2 | c.2005C>T p.R669C (on ENST00000649389 / NM_001366849.2; = p.R612C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs184913639, COSV50857055; called by muse, mutect2, varscan2
- SUCO | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as COSV55266327, COSV55272095; called by muse, mutect2, varscan2
- SUN2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs201794535, COSV53306198; called by muse, mutect2, varscan2
- SUPT3H | c.663G>T p.E221D (on ENST00000371460 / NM_181356.3; = p.E210D on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV60953506; called by muse, mutect2, varscan2
- SVEP1 | c.2371C>A p.R791S | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1318656976, COSV57049792; called by muse, mutect2, varscan2
- SYNPO2L | c.1861A>G p.T621A (on ENST00000394810 / NM_001114133.3; = p.T397A on NM_024875.5) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV65739310; called by muse, mutect2, varscan2
- SYT16 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746304551, COSV70854813; called by muse, mutect2, varscan2
- SYT3 | c.152T>G p.I51S | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV58899490; called by muse, mutect2
- SYT9 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs567812209, COSV59626171; called by muse, mutect2, varscan2
- TAF15 | c.1249G>A p.G417S (on ENST00000605844 / NM_139215.3; = p.G414S on NM_003487.4) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs554593706; called by muse, mutect2
- TAF6L | c.1189T>C p.W397R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53671276; called by muse, mutect2, varscan2
- TAOK1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1322906591, COSV55588426; called by muse, mutect2, varscan2
- TAS2R14 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV67863301; called by muse, mutect2, varscan2
- TBC1D31 | c.1893del p.H632Tfs*8 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | catalogued as rs768246273; called by mutect2, varscan2
- TCF19 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52565210; called by muse, mutect2
- TECTA | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.031); catalogued as COSV50825562; called by muse, mutect2, varscan2
- TENM1 | c.2485T>A p.Y829N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as COSV64445808; called by muse, mutect2, varscan2
- TEP1 | c.6395T>C p.L2132P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53001574; called by muse, mutect2, varscan2
- TERF1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs533827129, COSV52577343; called by muse, mutect2, varscan2
- TEX10 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs370862568, COSV100887966; called by muse, mutect2, varscan2
- TFEB | c.1400G>T p.S467I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57827118; called by muse, mutect2
- THBS4 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63471224; called by muse, mutect2, varscan2
- THOC7 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1161114052, COSV55734883; called by muse, mutect2, varscan2
- THRAP3 | c.2269dup p.T757Nfs*6 | Frame Shift Ins (INS) | VAF 20/75 reads (27%) | catalogued as rs1443424346; called by mutect2, pindel, varscan2
- TM2D3 | c.677C>T p.T226M (on ENST00000333202 / NM_078474.3; = p.T200M on NM_025141.3) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754640606, COSV60881089; called by muse, mutect2, varscan2
- TMEM255B | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs747109815, COSV64704552; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs781830688; called by mutect2, varscan2
- TNRC18 | c.8152G>T p.G2718C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV100078679; called by muse, mutect2, varscan2
- TNXB | c.9067C>T p.R3023W (on ENST00000647633; = p.R2776W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs771834644, COSV64490291; called by muse, mutect2, varscan2
- TRAF3IP3 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767332069, COSV50563064; called by muse, mutect2, varscan2
- TRAF6 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.091); catalogued as COSV61923822; called by muse, mutect2, varscan2
- TRANK1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs755000515, COSV57166317; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs770561785; called by mutect2, varscan2
- TRIM10 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1469631434, COSV65000324; called by muse, mutect2, varscan2
- TRIM14 | c.575T>C p.M192T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV58355713; called by muse, mutect2, varscan2
- TRIM29 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs781322131, COSV59282365; called by muse, mutect2, varscan2
- TRIO | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV60098295; called by muse, mutect2, varscan2
- TRMT5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 52/238 reads (22%) | catalogued as rs1205039911, COSV50781130, COSV50786974; called by muse, mutect2, varscan2
- TTF1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.053); catalogued as COSV57507856; called by muse, mutect2, varscan2
- TTN | c.2699del p.K900Rfs*3 (on ENST00000591111; = p.K854Rfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as COSV60035655, COSV60133047; called by mutect2, pindel, varscan2
- TUBA3E | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56060058; called by muse, mutect2, varscan2
- TUBB6 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.717); catalogued as rs1440920955, COSV52316505; called by muse, mutect2, varscan2
- TUBGCP2 | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV99427447; called by muse, mutect2
- TUBGCP2 | c.506del p.N169Ifs*19 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs372605588; called by mutect2, varscan2
- UBC | c.634A>G p.N212D | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV60059200; called by muse, mutect2, varscan2
- UBE2O | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60068308; called by muse, mutect2, varscan2
- UBE4B | c.1721C>T p.P574L (on ENST00000343090 / NM_001105562.3; = p.P445L on NM_006048.5) | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs754119546, COSV53543709; called by muse, mutect2, varscan2
- UBR4 | c.11195G>A p.R3732Q | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs552952185, COSV64400509, COSV64401468; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 27/138 reads (20%) | catalogued as rs763652408; called by mutect2, varscan2
- UGT2B28 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV59434808; called by muse, mutect2, varscan2
- ULK4 | c.1778del p.K593Rfs*17 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as rs76318575; called by mutect2, varscan2
- UNC5B | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as rs566257491, COSV58976289; called by muse, mutect2, varscan2
- UNC79 | c.2237G>A p.R746Q (on ENST00000393151 / NM_001346218.2; = p.R569Q on NM_020818.5) | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as rs576321999, COSV56415495; called by muse, mutect2, varscan2
- UPK2 | c.150del p.C51Vfs*10 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs750952264; called by mutect2, pindel, varscan2
- USF2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1425963674, COSV55888430, COSV55888518; called by muse, mutect2, varscan2
- USP2 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52732617; called by muse, mutect2, varscan2
- USP6 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs764268758, COSV51497206; called by muse, mutect2, varscan2
- UST | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746546399, COSV66549397, COSV66550910; called by muse, mutect2, varscan2
- UTY | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV58873003; called by muse, mutect2, varscan2
- VANGL2 | c.940A>C p.N314H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs778018773, COSV63605603; called by muse, mutect2, varscan2
- VPS13B | c.2722A>G p.K908E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV62159753; called by muse, mutect2, varscan2
- VPS26B | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV55546821, COSV99845259; called by muse, mutect2, varscan2
- VRTN | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56440957, COSV56444142, COSV99832434; called by muse, mutect2, varscan2
- VSIG4 | c.55+2T>C p.X19_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101038116; called by muse, mutect2, varscan2
- WBP11 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as rs906649040, COSV53765128; called by muse, mutect2, varscan2
- WDR24 | c.983G>A p.R328Q (on ENST00000248142; = p.R198Q on NM_032259.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1313629797, COSV50202365, COSV99555987; called by muse, mutect2, varscan2
- WFS1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); catalogued as rs369795224, CM024435; ClinVar: uncertain significance; called by muse, mutect2
- WNT5A | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV52839696; called by muse, mutect2, varscan2
- WWC1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs781547786, COSV54652609; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | catalogued as rs745648385; called by mutect2, pindel, varscan2
- XIRP2 | c.5316dup p.D1773Rfs*3 (on ENST00000628543; = p.D1948Rfs*3 on NM_152381.6) | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs760810271; called by mutect2, varscan2
- XIRP2 | c.8190A>C p.Q2730H (on ENST00000628543; = p.Q2905H on NM_152381.6) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs768731520, COSV54738931; called by muse, mutect2, varscan2
- XYLT2 | c.1205T>C p.F402S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV50023366; called by muse, mutect2, varscan2
- ZBED9 | c.61dup p.E21Gfs*8 | Frame Shift Ins (INS) | VAF 22/79 reads (28%) | catalogued as rs1251431620; called by mutect2, pindel, varscan2
- ZBTB45 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs778200787, COSV63525463; called by muse, mutect2, varscan2
- ZBTB7C | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as rs774550186, COSV59688255; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFP69 | c.85del p.A29Rfs*7 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as COSV65528879, COSV65529298; called by mutect2, pindel
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF135 | c.1235G>A p.C412Y (on ENST00000313434 / NM_001289401.2; = p.C424Y on NM_003436.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536982, COSV57886663; called by muse, mutect2, varscan2
- ZNF14 | c.1565A>G p.E522G | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.876); catalogued as COSV59851814; called by muse, mutect2
- ZNF169 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369966911; called by muse, mutect2, varscan2
- ZNF248 | c.690del p.F230Lfs*8 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as COSV61997619; called by mutect2, pindel, varscan2
- ZNF284 | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69691810; called by muse, mutect2, varscan2
- ZNF33B | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs367988227; called by muse, mutect2, varscan2
- ZNF385D | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs775043635, COSV55778234; called by muse, mutect2, varscan2
- ZNF428 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV56195465; called by muse, mutect2, varscan2
- ZNF462 | c.3256G>T p.G1086C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52952649; called by muse, mutect2, varscan2
- ZNF479 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.722); catalogued as COSV100482568; called by muse, mutect2, varscan2
- ZNF572 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60003046; called by muse, mutect2, varscan2
- ZNF585B | c.1485A>G p.I495M | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs762910218, COSV100459365; called by muse, mutect2, varscan2
- ZNF626 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV74131134; called by muse, mutect2, varscan2
- ZNF638 | c.2829+2T>C p.X943_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100038331; called by muse, mutect2, varscan2
- ZNF684 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV65519817; called by muse, mutect2, varscan2
- ZNF689 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.185); catalogued as COSV54910268; called by muse, mutect2, varscan2
- ZNF700 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs751845890, COSV54315745; called by muse, mutect2, varscan2
- ZNF793 | c.862del p.C288Vfs*113 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs761241629, COSV101495729; called by mutect2, varscan2
- ZNF808 | c.71T>C p.L24S | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63121978; called by muse, mutect2, varscan2
- ZNF862 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs376877827; called by muse, mutect2, varscan2
- ZRANB3 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs753002480, COSV51492938; called by muse, mutect2, varscan2
- AAAS | c.1523del p.G508Vfs*43 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- ABCA7 | c.5371del p.D1791Mfs*5 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- ADAM29 | c.2101dup p.S701Kfs*2 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- AKAP13 | c.1881_1883del p.E627del | In Frame Del (DEL) | VAF 35/119 reads (29%) | called by pindel, varscan2
- AKTIP | c.137del p.N46Mfs*5 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- ALCAM | c.458del p.K153Sfs*34 | Frame Shift Del (DEL) | VAF 49/184 reads (27%) | called by mutect2, pindel, varscan2
- ARAF | c.644_649del p.T215_P216del | In Frame Del (DEL) | VAF 17/27 reads (63%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- ARNTL | c.1381del p.H461Tfs*35 (on ENST00000403290 / NM_001297719.2; = p.H460Tfs*35 on NM_001178.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, varscan2
- ATP2A1 | c.1499del p.P500Qfs*38 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.1007_1026del p.P336Rfs*37 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- BAZ1A | c.2830dup p.S944Ffs*7 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- BAZ2B | c.70_72del p.S24del | In Frame Del (DEL) | VAF 34/105 reads (32%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- CC2D2B | c.628del p.S210Vfs*2 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- CCDC142 | c.2224del p.S742Pfs*52 (on ENST00000393965 / NM_001365575.2; = p.S735Pfs*52 on NM_032779.4) | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- CCDC38 | c.447del p.A150Qfs*24 | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | called by mutect2, pindel, varscan2
- CCR8 | c.689del p.N230Tfs*45 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- CENPF | c.8869del p.S2957Afs*6 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- CFAP251 | c.1206del p.F402Lfs*10 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- CHRM1 | c.1064_1066del p.F355del | In Frame Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- CLGN | c.327_328del p.G110Tfs*6 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by pindel, varscan2
- CNPPD1 | c.971del p.P324Qfs*89 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- COL26A1 | c.546del p.D183Tfs*166 (on ENST00000313669 / NM_001278563.3; = p.D181Tfs*166 on NM_133457.4) | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- CYP4F22 | c.381del p.K128Rfs*9 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- CYP51A1 | c.1070_1072del p.P357del | In Frame Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- DENND1C | c.1436del p.G479Afs*3 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel
- DENND5B | c.1530dup p.T511Yfs*32 | Frame Shift Ins (INS) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- DGKB | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2
- DIP2C | c.3107del p.P1036Qfs*3 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- DIP2C | c.453del p.T152Pfs*50 | Frame Shift Del (DEL) | VAF 35/133 reads (26%) | called by mutect2, pindel, varscan2
- DTNA | c.1796del p.G599Efs*15 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- EDAR | c.346_350del p.C116Pfs*137 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- EIF4E3 | c.523_525del p.V175del (on ENST00000425534 / NM_001134651.2; = p.V69del on NM_173359.5) | In Frame Del (DEL) | VAF 17/60 reads (28%) | called by pindel, varscan2
- FAM83E | c.889del p.Q297Rfs*6 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- FBXO33 | c.703dup p.I235Nfs*2 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, varscan2
- FCHO1 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- FFAR2 | c.927dup p.T310Dfs*3 | Frame Shift Ins (INS) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- FRA10AC1 | c.549dup p.E184Rfs*9 | Frame Shift Ins (INS) | VAF 30/148 reads (20%) | called by mutect2, pindel, varscan2
- GDA | c.134del p.L45* | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- GOLGA6L22 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.316); called by muse, varscan2
- GPR39 | c.998del p.F333Sfs*78 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- HEATR5A | c.1000del p.S334Lfs*4 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- HEXIM2 | c.52dup p.L18Pfs*18 | Frame Shift Ins (INS) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- HNMT | c.263_265del p.V88del | In Frame Del (DEL) | VAF 16/59 reads (27%) | called by pindel, varscan2
- HOXD8 | c.330del p.P111Lfs*66 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by pindel, varscan2
- IRF2 | c.102dup p.Q35Sfs*9 | Frame Shift Ins (INS) | VAF 33/88 reads (38%) | called by pindel, varscan2
- ITPR2 | c.5509del p.R1837Gfs*7 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, varscan2
- ITPR2 | c.5405dup p.S1803Vfs*6 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- ITPRIP | c.330del p.S112Hfs*64 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- IVNS1ABP | c.332dup p.L112Afs*12 | Frame Shift Ins (INS) | VAF 23/169 reads (14%) | called by mutect2, pindel, varscan2
- IWS1 | c.2404del p.S802Afs*7 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- IWS1 | c.689del p.P230Qfs*160 | Frame Shift Del (DEL) | VAF 57/246 reads (23%) | called by mutect2, pindel, varscan2
- KCNH3 | c.422del p.G141Afs*67 | Frame Shift Del (DEL) | VAF 39/156 reads (25%) | called by mutect2, pindel, varscan2
- KCTD3 | c.133del p.S45Pfs*4 | Frame Shift Del (DEL) | VAF 31/171 reads (18%) | called by mutect2, varscan2
- KDM5C | c.4523del p.P1508Lfs*36 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel
- KIFAP3 | c.163del p.I55Sfs*13 | Frame Shift Del (DEL) | VAF 45/88 reads (51%) | called by mutect2, pindel, varscan2
- KMT2D | c.5058del p.K1686Nfs*36 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- MAP2K7 | c.1117_1119del p.K373del | In Frame Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.924del p.F308Lfs*9 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- MBD1 | c.1797del p.K599Nfs*66 (on ENST00000269468 / NM_001323950.1; = p.K497Nfs*? on NM_002384.2) | Frame Shift Del (DEL) | VAF 60/231 reads (26%) | called by mutect2, varscan2
- MIA3 | c.2076dup p.H693Sfs*17 | Frame Shift Ins (INS) | VAF 32/142 reads (23%) | called by mutect2, pindel, varscan2
- MOCOS | c.775_795del p.P259_I265del | In Frame Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- MUC4 | c.14597del p.F4866Sfs*5 (on ENST00000463781 / NM_018406.7; = p.F630Sfs*5 on NM_004532.6) | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.1124del p.K375Sfs*4 (on ENST00000357337; = p.K413Sfs*4 on NM_015057.5) | Frame Shift Del (DEL) | VAF 35/147 reads (24%) | called by mutect2, pindel, varscan2
- NACC2 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- NANS | c.234dup p.K79Efs*15 | Frame Shift Ins (INS) | VAF 48/218 reads (22%) | called by mutect2, pindel, varscan2
- NKIRAS2 | c.281_282del p.F94Sfs*11 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- NR2F1 | c.328_330del p.F110del | In Frame Del (DEL) | VAF 12/28 reads (43%) | called by pindel, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- PARP16 | c.155_156del p.C52* | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- PARP4 | c.2541del p.K847Nfs*25 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.1499G>T p.S500I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2
- PDS5B | c.3658del p.T1220Rfs*10 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- PHACTR4 | c.1037del p.P346Hfs*33 (on ENST00000373839 / NM_001350159.2; = p.P356Hfs*33 on NM_023923.4) | Frame Shift Del (DEL) | VAF 73/235 reads (31%) | called by mutect2, pindel, varscan2
- PHYH | c.683del p.G228Efs*22 | Frame Shift Del (DEL) | VAF 78/320 reads (24%) | called by mutect2, pindel, varscan2
- PIAS4 | c.1308del p.S437Afs*156 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- PLA2G15 | c.695del p.G232Afs*23 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- POTEE | c.2428del p.L810* | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, varscan2
- PRAMEF14 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKDC | c.8287del p.M2763* | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- PTPN13 | c.4755_4756del p.C1586Qfs*11 (on ENST00000411767 / NM_080683.3; = p.C1567Qfs*11 on NM_006264.3) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2*
- RAB20 | c.217del p.A73Rfs*10 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- RBM28 | c.1014dup p.I339Yfs*7 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 39/138 reads (28%) | called by mutect2, varscan2
- RPL12 | c.263del p.P88Hfs*34 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- RPS6KB1 | c.1294del p.I432Sfs*50 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- SASH3 | c.117del p.V40Wfs*2 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- SCUBE1 | c.728-3dup | Splice Region (INS) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- SEMA5A | c.2709_2752delinsTGAGTGTGAA p.D904Efs*44 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2*
- SERPINI1 | c.248del p.N83Mfs*8 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2
- SETBP1 | c.412del p.D138Tfs*69 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, varscan2
- SEZ6 | c.2531dup p.E845* | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
297 further variants in this file (28 protein-altering or splice-affecting, 243 silent, 26 other) are not listed here.
